MMRF case MMRF_1169 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/27481a52-2d4e-49bd-8237-e04432ef6864

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 191 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.9 years (27,363 days); ISS stage: III; Days to last known disease status: 191 days; Days to last follow up: 191 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 139 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 139 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 191.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -33 (ECOG 1): M Protein 9.2 g/dL; Immunoglobulin G 21.5 g/L; Immunoglobulin A 6.6 g/L; Immunoglobulin M 53.5 g/L; Beta 2 Microglobulin 11.9 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 3.25 mmol/L; Albumin 25 g/L; Total Protein 10 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 2.73 mg/dL.
- Day 87 (ECOG 1): M Protein 0.5 g/dL; Immunoglobulin G 5.59 g/L; Immunoglobulin A 29.8 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 1.4 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.76 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 21 g/L; Total Protein 9.3 g/dL; Glucose 7.92 mmol/L.
- Day 177 (ECOG 2): M Protein 1.2 g/dL; Immunoglobulin G 2.4 g/L; Immunoglobulin A 44.6 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 7.28 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 22.9 ×10⁹/L; Platelets 31 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.83 mmol/L; Albumin 18 g/L; Total Protein 9.7 g/dL; Glucose 6.22 mmol/L.

Other clinical attributes
- Day -33: Weight: 107 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1169_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -33 days.
- Sample MMRF_1169_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -33 days.
